CPTAC case C3L-03392 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/91c8eda3-ad8f-4a80-9f35-f6552f6452c0

Demographics
Sex at birth: female; Race: white; Year of birth: 1967; Vital status: Dead; Days to death: 147 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 50.7 years (18,509 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 147 days; Days to last follow up: -9 days.
   Pathology details: Greatest tumor dimension: 5.1 cm.

Follow-up (1 entry)
- Days to follow up: -9 days; Disease response: With Tumor; Karnofsky performance status: 0.

Other clinical attributes
- Weight: 71 kg; Height: 159 cm; BMI: 28.08.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03392-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 100 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03392-21: Section location: Right hemisphere parietal lobe; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-03392-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 100 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03392-23: Section location: Right hemisphere parietal lobe; Percent tumor nuclei: 70; Percent necrosis: 15.
- Sample C3L-03392-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
